Somatic mutation profile of tumor specimen TCGA-HZ-7922-01A (aliquot TCGA-HZ-7922-01A-11D-2154-08) from TCGA case TCGA-HZ-7922, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 61.4 years (22,413 days).
Specimen TCGA-HZ-7922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98ef018b-d03c-4ae2-990e-037ad9e220d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-7922-10A (Blood Derived Normal), aliquot TCGA-HZ-7922-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4d89c64-6b93-4d7c-88ab-7461440413b6

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 31, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.3544dup p.L1182Pfs*38 | Frame Shift Ins (INS) | VAF 23/72 reads (32%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 197/497 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 88/222 reads (40%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACE2 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 140/743 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.513); catalogued as rs144869363, COSV99382551; called by muse, mutect2, varscan2
- ADGRL4 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100875595; called by muse, mutect2, varscan2
- ARID2 | c.1123A>G p.M375V | Missense Mutation (SNP) | VAF 151/711 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV100535431; called by muse, mutect2, varscan2
- ATRIP | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 244/593 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100202673, COSV100202801; called by muse, mutect2, varscan2
- C14orf39 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549495863, COSV58786050; called by muse, mutect2, varscan2
- CAPNS1 | c.210-1G>A p.X70_splice | Splice Site (SNP) | VAF 182/663 reads (27%) | catalogued as COSV99874452; called by muse, mutect2, varscan2
- CARMIL2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV58023398; called by muse, mutect2, varscan2
- CDC14A | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV100324455; called by muse, mutect2, varscan2
- COL6A2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142880107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 283/1889 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV50385005; called by muse, mutect2, varscan2
- ERICH3 | c.3923C>T p.A1308V | Missense Mutation (SNP) | VAF 122/883 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138615520, COSV58603156, COSV58612337; called by muse, mutect2, varscan2
- FLNC | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 148/381 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1202164075, COSV100367640; called by muse, mutect2, varscan2
- GDF6 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54625724; called by muse, mutect2, varscan2
- GOLPH3 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 175/626 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.121); catalogued as rs1258812711, COSV99417012; called by muse, mutect2, varscan2
- GTF3A | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101142087; called by muse, mutect2, varscan2
- KCNA6 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 20/612 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99768344; called by muse, mutect2
- KCNT2 | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs773845489, COSV54068516; called by muse, mutect2, varscan2
- KLK1 | c.685T>A p.S229T | Missense Mutation (SNP) | VAF 161/412 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100032514; called by muse, mutect2, varscan2
- LRBA | c.2440C>G p.Q814E | Missense Mutation (SNP) | VAF 130/348 reads (37%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.833); catalogued as COSV100840966; called by muse, mutect2, varscan2
- MGRN1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | catalogued as COSV99273776; called by muse, mutect2, varscan2
- MROH7 | c.1684A>T p.S562C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100272896; called by muse, mutect2
- NCOR1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV99247461; called by muse, mutect2, varscan2
- NLGN3 | c.2392C>T p.R798C (on ENST00000358741 / NM_181303.2; = p.R778C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1445089858, COSV62442724; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 213/1007 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2, varscan2
- PCDH9 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 52/652 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as COSV100118543; called by muse, mutect2
- PHLDB3 | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99415189; called by muse, mutect2
- PSKH1 | c.960C>G p.P320= | Splice Region (SNP) | VAF 180/522 reads (34%) | catalogued as COSV99344476; called by muse, mutect2, varscan2
- RAB3IP | c.1351G>A p.D451N (on ENST00000550536 / NM_175623.4; = p.D435N on NM_022456.5) | Missense Mutation (SNP) | VAF 105/548 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV99922952; called by muse, mutect2, varscan2
- ROBO1 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458312; called by muse, mutect2, varscan2
- SH2D3C | c.1529C>T p.A510V (on ENST00000314830 / NM_170600.3; = p.A353V on NM_005489.4) | Missense Mutation (SNP) | VAF 343/987 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs142472912, COSV59127009; called by muse, mutect2, varscan2
- SPRYD3 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 143/614 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as rs1199835566, COSV100036569; called by muse, mutect2, varscan2
- TNRC18 | c.3952G>A p.G1318S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs547812685, COSV101269565; called by muse, mutect2, varscan2
- CGNL1 | c.3204del p.D1068Efs*34 | Frame Shift Del (DEL) | VAF 166/809 reads (21%) | called by mutect2, pindel, varscan2
- FCGBP | c.9353A>G p.D3118G | Missense Mutation (SNP) | VAF 90/1170 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2
- MYLPF | c.471del p.Y158Tfs*35 | Frame Shift Del (DEL) | VAF 45/386 reads (12%) | called by mutect2, pindel, varscan2
- AMOT | c.1668G>A p.A556= (on ENST00000371959 / NM_001113490.1; = p.A147= on NM_133265.3) | Silent (SNP) | VAF 494/1302 reads (38%) | catalogued as rs757259461, COSV100494736; called by muse, mutect2, varscan2
- KLK1 | c.684A>C p.T228= | Silent (SNP) | VAF 160/413 reads (39%) | catalogued as COSV100032516; called by muse, mutect2, varscan2
- NEFH | c.2688G>A p.E896= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as COSV100151260; called by muse, mutect2, varscan2
- OR4D5 | c.60T>C p.V20= | Silent (SNP) | VAF 45/554 reads (8%) | catalogued as COSV100189757; called by muse, mutect2
- PCDH9 | c.345G>T p.V115= | Silent (SNP) | VAF 52/657 reads (8%) | catalogued as COSV100118545; called by muse, mutect2
- TBC1D12 | c.1635A>G p.E545= | Silent (SNP) | VAF 74/445 reads (17%) | catalogued as COSV99831171; called by muse, mutect2, varscan2
- TRIM58 | c.891C>T p.P297= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs745534672, COSV63572003; called by muse, mutect2, varscan2
- TTN | c.25104C>T p.S8368= (on ENST00000591111; = p.S7441= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 350/1015 reads (34%) | catalogued as rs727505250, COSV59868777; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- VRK3 | c.579A>G p.S193= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as COSV100371315; called by muse, mutect2, varscan2
- XDH | c.141C>A p.G47= | Silent (SNP) | VAF 55/506 reads (11%) | called by muse, mutect2, varscan2
